Somatic mutation profile of tumor specimen TCGA-HT-7856-01A (aliquot TCGA-HT-7856-01A-11D-2395-08) from TCGA case TCGA-HT-7856, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 36.0 years (13,145 days).
Specimen TCGA-HT-7856-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50e3c1bf-aa1e-47d7-a655-4956ed6eb581.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7856-10A (Blood Derived Normal), aliquot TCGA-HT-7856-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a2de335-986a-4e48-9fd5-0cedd1a5eb5f

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 6, Silent 5, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.514A>T p.R172W | Missense Mutation (SNP) | VAF 10/70 reads (14%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1057519906, COSV57468942, COSV57468989, COSV57477941; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MERTK | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs878853354, CM148731, COSV54927455; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- GRIA2 | c.181C>A p.H61N | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.984); catalogued as COSV99643670; called by muse, mutect2
- MAST3 | c.1934G>A p.W645* | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | catalogued as COSV53219444; called by muse, mutect2
- POU1F1 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as rs1312054803, COSV60155059; called by muse, mutect2
- RYR1 | c.11561G>A p.G3854E | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV62094286; called by muse, mutect2
- SIN3A | c.1855-2A>G p.X619_splice | Splice Site (SNP) | VAF 5/51 reads (10%) | catalogued as COSV64582455; called by muse, mutect2
- PIK3CA | c.2521A>G p.I841V | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0.024); called by muse, mutect2
- AMHR2 | c.1674C>T p.G558= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as COSV57685439; called by muse, mutect2, varscan2
- ANKRD52 | c.1473T>C p.S491= | Silent (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
- CLCNKB | c.1182G>A p.P394= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV65160261; called by muse, mutect2, varscan2
- IMPDH1 | c.558G>A p.V186= (on ENST00000470772 / NM_001142573.2; = p.V272= on NM_000883.4) | Silent (SNP) | VAF 23/164 reads (14%) | catalogued as COSV58315611; called by muse, mutect2, varscan2
- JAM3 | c.891C>T p.D297= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs150992119; called by muse, mutect2, varscan2
